Somatic mutation profile of tumor specimen TCGA-DX-A3UD-01A (aliquot TCGA-DX-A3UD-01A-11D-A307-09) from TCGA case TCGA-DX-A3UD, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 56.7 years (20,703 days).
Specimen TCGA-DX-A3UD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff512418-e051-4b5f-998a-bf65409632aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A3UD-10A (Blood Derived Normal), aliquot TCGA-DX-A3UD-10A-01D-A307-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a6dada9-aad1-4778-b8b1-57364a254a42

The open-access MAF lists 31 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 7, Splice Site 2, Frame Shift Del 1, 3'UTR 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP3B2 | c.258C>A p.N86K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV99915953; called by muse, mutect2, varscan2
- ATRX | c.1330C>T p.R444* | Nonsense Mutation (SNP) | VAF 46/50 reads (92%) | catalogued as COSV64880893; called by muse, mutect2, varscan2
- C1orf105 | c.209A>T p.N70I | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs1308808213, COSV100877902; called by muse, mutect2, varscan2
- CAMTA1 | c.116-1G>A p.X39_splice | Splice Site (SNP) | VAF 24/41 reads (59%) | catalogued as COSV100345494; called by muse, mutect2, varscan2
- CDCA2 | c.1996T>C p.S666P | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as rs773111155, COSV100398707; called by muse, mutect2, varscan2
- COPS7B | c.636G>T p.E212D | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.935); catalogued as COSV100602169; called by muse, mutect2
- DPH1 | c.364G>T p.A122S | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV99559393; called by muse, mutect2, varscan2
- DSG3 | c.685-1G>T p.X229_splice | Splice Site (SNP) | VAF 41/79 reads (52%) | catalogued as COSV99933642; called by muse, mutect2, varscan2
- FKBP6 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99333613; called by muse, mutect2, varscan2
- KIAA1549 | c.3019G>A p.V1007I | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT tolerated (0.22); PolyPhen benign (0.068); catalogued as rs376801932; called by muse, mutect2, varscan2
- KRTAP10-1 | c.284G>C p.C95S | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV100551480; called by muse, mutect2, varscan2
- LAMA1 | c.2361C>A p.D787E | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as COSV101054645; called by muse, mutect2, varscan2
- MCCC1 | c.1186A>G p.M396V | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as rs775316461, COSV99659286; called by muse, mutect2, varscan2
- MTMR14 | c.1817C>T p.S606L (on ENST00000296003 / NM_001077525.3; = p.S494L on NM_022485.5) | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.115); catalogued as COSV56004166; called by muse, mutect2, varscan2
- OR2F2 | c.648G>C p.L216F | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.81); PolyPhen benign (0.094); catalogued as COSV101283791; called by muse, mutect2, varscan2
- PSTPIP2 | c.715T>C p.S239P | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101297329; called by muse, mutect2, varscan2
- RGS17 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs867798428, COSV99242381; called by muse, mutect2
- SCN5A | c.4018G>A p.V1340I (on ENST00000333535 / NM_198056.3; = p.V1339I on NM_000335.5) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199473605, CM100703, COSV61128014; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SHC4 | c.727G>A p.V243I | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.102); catalogued as COSV100194108; called by muse, mutect2, varscan2
- UNC79 | c.1238G>C p.S413T (on ENST00000393151 / NM_001346218.2; = p.S236T on NM_020818.5) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV99825323, COSV99829506; called by muse, mutect2, varscan2
- C19orf44 | c.1417_1426del p.E473Qfs*3 | Frame Shift Del (DEL) | VAF 27/54 reads (50%) | called by mutect2, pindel, varscan2
- GRAP2 | c.572dup p.T192Dfs*47 | Frame Shift Ins (INS) | VAF 37/83 reads (45%) | called by mutect2, pindel, varscan2
- SEC24D | c.2028C>A p.D676E | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- GRM6 | c.2103C>A p.T701= | Silent (SNP) | VAF 54/87 reads (62%) | catalogued as COSV99179421; called by muse, varscan2
- MRGPRX1 | c.831C>A p.S277= | Silent (SNP) | VAF 73/78 reads (94%) | catalogued as COSV100245815, COSV57106293; called by muse, mutect2, varscan2
- OR2T35 | c.756C>T p.Y252= | Silent (SNP) | VAF 45/101 reads (45%) | catalogued as rs747627097, COSV100442116; called by muse, mutect2, varscan2
- PNPLA3 | c.876G>A p.L292= | Silent (SNP) | VAF 31/58 reads (53%) | catalogued as rs149395579; called by muse, mutect2, varscan2
- SGSM1 | c.585C>T p.P195= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV101240351; called by muse, mutect2, varscan2
- SLC39A5 | c.241C>T p.L81= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as COSV99907305; called by muse, mutect2, varscan2
- TIAL1 | c.621G>A p.V207= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs764333440, COSV100958325; called by muse, mutect2, varscan2
- OSCAR | c.*433C>T | 3'UTR (SNP) | VAF 14/47 reads (30%) | catalogued as rs1360963507, COSV99499790; called by muse, mutect2, varscan2
